Somatic mutation profile of tumor specimen MMRF_2507_1_BM_CD138pos (aliquot MMRF_2507_1_BM_CD138pos_T1_KHS5U_L13766) from MMRF case MMRF_2507, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.5 years (25,035 days).
Specimen MMRF_2507_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df420f45-19b4-4b1c-8a4c-2eaa941be97e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2507_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2507_1_PB_Whole_C3_KHS5U_L13767; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51e2a49f-84b7-49a7-8742-28f9f49b1d3b

The open-access MAF lists 106 somatic variants for this specimen: 35 protein-altering or splice-affecting, 16 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 30, Missense Mutation 30, Silent 16, Intron 10, 5'UTR 6, 3'Flank 4, 5'Flank 3, Nonsense Mutation 3, RNA 2, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 63/127 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.124); catalogued as rs1036164993; called by muse, mutect2, varscan2
- ADCY1 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 123/251 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV52037127; called by muse, mutect2, varscan2
- CRACR2B | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs750040448; called by muse, mutect2, varscan2
- DSC2 | c.1762A>T p.T588S | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs954839841; called by muse, mutect2, varscan2
- EPHA7 | c.1194C>G p.N398K | Missense Mutation (SNP) | VAF 81/146 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as COSV65193085; called by muse, mutect2, varscan2
- HLTF | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs372129397; called by muse, mutect2, varscan2
- IGHV2-70 | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 69/73 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs745462696; called by muse, varscan2
- IGLV3-1 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs181792449; called by muse, mutect2, varscan2
- IL4I1 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.454); catalogued as COSV55577954, COSV55578822; called by muse, mutect2, varscan2
- PCDHA8 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 93/338 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.39); catalogued as COSV65337750; called by muse, mutect2, varscan2
- RIPK4 | c.2125G>A p.A709T (on ENST00000352483; = p.A661T on NM_020639.3) | Missense Mutation (SNP) | VAF 114/180 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs751402843; called by muse, mutect2, varscan2
- RYR3 | c.10157A>G p.Q3386R (on ENST00000389232; = p.Q3387R on NM_001036.6) | Missense Mutation (SNP) | VAF 89/136 reads (65%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.569); catalogued as rs756431186; called by muse, mutect2, varscan2
- TRAP1 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 42/118 reads (36%) | catalogued as rs779336548; called by muse, mutect2, varscan2
- ZNF534 | c.1738C>T p.R580* (on ENST00000332323 / NM_001143939.3; = p.R567* on NM_001143938.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 132/402 reads (33%) | catalogued as rs578064178, COSV56514210; called by muse, varscan2
- ZNF541 | c.1745C>A p.A582E | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.181); catalogued as COSV99645496; called by muse, mutect2, varscan2
- BEND5 | c.436A>C p.N146H | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CANX | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 97/311 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLOCK | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- EEF1AKNMT | c.1148T>C p.V383A (on ENST00000361735 / NM_015935.5; = p.V297A on NM_014955.3) | Missense Mutation (SNP) | VAF 80/124 reads (65%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMD4A | c.2122C>T p.R708W | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FZD3 | c.663_665del p.F221del | In Frame Del (DEL) | VAF 91/97 reads (94%) | called by mutect2, pindel, varscan2
- HRG | c.1542A>C p.Q514H | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- KCNH1 | c.2179del p.A727Pfs*3 (on ENST00000271751 / NM_172362.3; = p.A700Pfs*3 on NM_002238.4) | Frame Shift Del (DEL) | VAF 30/144 reads (21%) | called by pindel, varscan2
- LIFR | c.140A>G p.K47R | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGAM2 | c.4047G>A p.W1349* | Nonsense Mutation (SNP) | VAF 54/108 reads (50%) | called by muse, mutect2, varscan2
- MICU2 | c.953T>G p.F318C | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYO15B | c.8660T>A p.V2887E | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLEKHG5 | c.3007C>A p.P1003T (on ENST00000400915 / NM_001042663.3; = p.P966T on NM_020631.6) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPARD | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- RADIL | c.1468T>G p.S490A | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SH2B3 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC13A1 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEAD2 | c.1244G>A p.R415K | Missense Mutation (SNP) | VAF 89/152 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- ZC3H14 | c.491A>T p.E164V | Missense Mutation (SNP) | VAF 174/360 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ASL | c.1023C>T p.A341= | Silent (SNP) | VAF 82/156 reads (53%) | catalogued as rs530889593; called by muse, varscan2
- CNOT3 | c.711G>A p.A237= | Silent (SNP) | VAF 159/245 reads (65%) | catalogued as rs200821584; called by muse, mutect2, varscan2
- EPS15 | c.2088T>G p.P696= | Silent (SNP) | VAF 61/63 reads (97%) | called by muse, mutect2, varscan2
- FAT3 | c.13452T>G p.T4484= | Silent (SNP) | VAF 131/387 reads (34%) | catalogued as rs1411100784; called by muse, mutect2, varscan2
- FNBP4 | c.2028C>A p.S676= | Silent (SNP) | VAF 39/166 reads (23%) | catalogued as COSV99771861, COSV99771974; called by muse, mutect2, varscan2
- H3C8 | c.61C>T p.L21= | Silent (SNP) | VAF 109/218 reads (50%) | catalogued as rs753073758; called by muse, mutect2, varscan2
- IGLV3-1 | c.252C>T p.N84= | Silent (SNP) | VAF 95/191 reads (50%) | catalogued as rs181381534; called by muse, varscan2
- KIF13B | c.5121C>T p.V1707= | Silent (SNP) | VAF 156/175 reads (89%) | called by muse, mutect2, varscan2
- MAP1A | c.3003C>G p.G1001= | Silent (SNP) | VAF 63/217 reads (29%) | called by muse, mutect2, varscan2
- MYO1F | c.1377C>T p.S459= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as rs780033132, COSV57802668; called by muse, mutect2, varscan2
- PIEZO2 | c.6583C>T p.L2195= | Silent (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- PPM1H | c.1464G>T p.R488= | Silent (SNP) | VAF 63/122 reads (52%) | called by muse, mutect2, varscan2
- S1PR2 | c.627C>T p.Y209= | Silent (SNP) | VAF 60/205 reads (29%) | catalogued as rs145137562; called by muse, mutect2, varscan2
- SATB1 | c.255C>T p.N85= | Silent (SNP) | VAF 166/525 reads (32%) | catalogued as rs749293960; called by muse, mutect2, varscan2
- SNN | c.60T>A p.I20= | Silent (SNP) | VAF 60/270 reads (22%) | called by muse, mutect2, varscan2
- VGLL1 | c.723A>G p.S241= | Silent (SNP) | VAF 144/297 reads (48%) | called by muse, mutect2, varscan2
- AC124067.2 | n.214A>G | RNA (SNP) | VAF 70/78 reads (90%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-8709C>T | Intron (SNP) | VAF 122/177 reads (69%) | catalogued as rs569882219, COSV73145047; called by muse, mutect2, varscan2
- AGRN | c.*567C>T | 3'UTR (SNP) | VAF 69/136 reads (51%) | called by muse, mutect2
- AMOTL1 | c.*262A>T | 3'UTR (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- ARID5B | c.*1796T>C | 3'UTR (SNP) | VAF 65/125 reads (52%) | called by muse, mutect2, varscan2
- ATG5 | c.*1643_*1652del | 3'UTR (DEL) | VAF 28/77 reads (36%) | called by mutect2, pindel, varscan2
- CAMK2B | c.1598-21C>G | Intron (SNP) | VAF 27/51 reads (53%) | called by muse, mutect2, varscan2
- CARF | c.*610T>C | 3'UTR (SNP) | VAF 53/111 reads (48%) | called by muse, mutect2, varscan2
- CCR7 | c.*798C>T | 3'UTR (SNP) | VAF 82/164 reads (50%) | called by muse, mutect2, varscan2
- CEP78 | c.-198G>C | 5'UTR (SNP) | VAF 24/109 reads (22%) | called by muse, mutect2, varscan2
- CLASRP | c.1875-44G>A | Intron (SNP) | VAF 45/131 reads (34%) | called by muse, mutect2, varscan2
- DBNL | c.*5585A>G | 3'UTR (SNP) | VAF 63/139 reads (45%) | called by muse, mutect2, varscan2
- DDX52 | c.*617A>T | 3'UTR (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- DENND2B | c.*608G>A | 3'UTR (SNP) | VAF 43/118 reads (36%) | called by muse, mutect2, varscan2
- DNAJC5 | c.*1576G>A | 3'UTR (SNP) | VAF 40/93 reads (43%) | catalogued as rs1208321754; called by muse, mutect2, varscan2
- DTX2P1 | n.499_505del | RNA (DEL) | VAF 61/120 reads (51%) | called by mutect2, pindel, varscan2
- ERGIC2 | c.*472G>C | 3'UTR (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- FAM131B | c.*396T>C | 3'UTR (SNP) | VAF 95/204 reads (47%) | catalogued as rs969960737; called by muse, mutect2, varscan2
- FAM76A | c.-72G>C | 5'UTR (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
- FGF5 | c.*1221dup | 3'UTR (INS) | VAF 29/72 reads (40%) | called by mutect2, varscan2
- GPIHBP1 | c.-40G>A | 5'UTR (SNP) | VAF 71/165 reads (43%) | catalogued as rs1159586352, COSV58209537; called by muse, mutect2, varscan2
- GRK5 | c.*554T>C | 3'UTR (SNP) | VAF 31/58 reads (53%) | called by muse, mutect2, varscan2
- HECTD4 | c.*2192T>G | 3'UTR (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- HEY1 | c.331+369A>T | Intron (SNP) | VAF 80/138 reads (58%) | catalogued as rs774185972, COSV61232657; called by muse, varscan2
- KLF6 | c.*3292A>T | 3'UTR (SNP) | VAF 47/92 reads (51%) | called by muse, mutect2, varscan2
- KMT5C | c.387-67C>T | Intron (SNP) | VAF 7/22 reads (32%) | catalogued as rs1385431426; called by muse, mutect2, varscan2
- LGI3 | c.*681del | 3'UTR (DEL) | VAF 76/83 reads (92%) | catalogued as rs11418959; called by mutect2, varscan2
- LRRN3 | c.-178T>C | 5'UTR (SNP) | VAF 48/110 reads (44%) | called by muse, mutect2, varscan2
- MRPL44 | c.*195C>G | 3'UTR (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- NCK1 | chr3:136949320 A>G | 3'Flank (SNP) | VAF 91/151 reads (60%) | called by muse, mutect2, varscan2
- NF1 | c.8113+21A>C | Intron (SNP) | VAF 64/150 reads (43%) | catalogued as rs1273555167; called by muse, mutect2, varscan2
- NFX1 | c.3039+386G>C | Intron (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- NTNG1 | chr1:107482826 C>T | 3'Flank (SNP) | VAF 37/78 reads (47%) | called by muse, mutect2, varscan2
- PHLDB1 | c.1828-1202C>T | Intron (SNP) | VAF 18/28 reads (64%) | called by muse, varscan2
- POU4F1 | c.*1442C>T | 3'UTR (SNP) | VAF 31/83 reads (37%) | called by muse, mutect2, varscan2
- RAPGEF3 | chr12:47735541 T>C | 3'Flank (SNP) | VAF 42/126 reads (33%) | called by muse, mutect2
- S100B | c.*246A>C | 3'UTR (SNP) | VAF 99/144 reads (69%) | called by muse, mutect2, varscan2
- S1PR3 | c.-147-2009C>T | Intron (SNP) | VAF 73/215 reads (34%) | called by muse, mutect2, varscan2
- SEC22C | c.*3077C>T | 3'UTR (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
- SLITRK1 | c.*871dup | 3'UTR (INS) | VAF 17/36 reads (47%) | catalogued as rs1228656976; called by mutect2, varscan2
- SNORA60 | chr20:38448032 del C | 5'Flank (DEL) | VAF 85/210 reads (40%) | called by mutect2, pindel, varscan2
- SPINK7 | c.87+194dup | Intron (INS) | VAF 5/16 reads (31%) | catalogued as rs954372391; called by mutect2, varscan2
- SPSB4 | c.-10G>A | 5'UTR (SNP) | VAF 16/70 reads (23%) | catalogued as COSV60147961; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*2283G>A | 3'UTR (SNP) | VAF 51/110 reads (46%) | called by muse, mutect2, varscan2
- TAF9 | chr5:69369716 T>A | 5'Flank (SNP) | VAF 74/279 reads (27%) | catalogued as rs764215466; called by muse, mutect2, varscan2
- TMEM107 | c.*700A>G | 3'UTR (SNP) | VAF 42/97 reads (43%) | catalogued as rs780174735; called by muse, mutect2
- TMEM125 | c.*261C>T | 3'UTR (SNP) | VAF 78/182 reads (43%) | catalogued as rs903548422; called by muse, mutect2, varscan2
- TMEM132E | chr17:34575050 T>A | 5'Flank (SNP) | VAF 31/52 reads (60%) | called by muse, mutect2, varscan2
- TNFSF11 | c.*574T>C | 3'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2
- TRAF3 | c.*4350dup | 3'UTR (INS) | VAF 23/51 reads (45%) | called by mutect2, pindel, varscan2
- UBXN10 | c.*3920A>C | 3'UTR (SNP) | VAF 84/173 reads (49%) | catalogued as rs547769440; called by muse, mutect2, varscan2
- WDR45B | c.*1252A>T | 3'UTR (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- ZBTB20 | chr3:114338467 A>G | 3'Flank (SNP) | VAF 33/123 reads (27%) | catalogued as rs1560089499; called by muse, mutect2, varscan2
- ZNF678 | c.-296A>G | 5'UTR (SNP) | VAF 60/190 reads (32%) | catalogued as rs925121015; called by muse, mutect2, varscan2
- ZNF831 | c.*469G>A | 3'UTR (SNP) | VAF 50/100 reads (50%) | called by muse, mutect2, varscan2
